Somatic mutation profile of tumor specimen TCGA-85-A4QQ-01A (aliquot TCGA-85-A4QQ-01A-41D-A25L-08) from TCGA case TCGA-85-A4QQ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,065 days).
Specimen TCGA-85-A4QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f65e2df5-63a9-47b5-9b2e-cc3800bfae26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A4QQ-10A (Blood Derived Normal), aliquot TCGA-85-A4QQ-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc26999e-3898-486f-a032-554d65f3f42f

The open-access MAF lists 339 somatic variants for this specimen: 255 protein-altering or splice-affecting, 79 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 79, Nonsense Mutation 16, Frame Shift Del 7, Splice Site 5, Intron 3, 3'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 75/216 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV101330188; called by muse, mutect2, varscan2
- ABCA13 | c.4252C>T p.Q1418* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV101330189; called by muse, mutect2, varscan2
- ABCC9 | c.4250G>A p.R1417K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99687338; called by muse, mutect2, varscan2
- ABCD2 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV100429819, COSV58049287; called by muse, mutect2, varscan2
- ABTB1 | c.1403A>T p.E468V (on ENST00000232744 / NM_172027.3; = p.E326V on NM_032548.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99230157; called by muse, mutect2, varscan2
- ACSM2A | c.286G>T p.V96F (on ENST00000219054; = p.V17F on NM_001308169.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs764727282, COSV99525531, COSV99525748; called by muse, mutect2, varscan2
- ADAMTS4 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.145); catalogued as COSV100917576; called by muse, mutect2, varscan2
- ADCY8 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as rs1563724934, COSV53903301, COSV99651047; called by muse, mutect2, varscan2
- ADGRV1 | c.4791G>C p.E1597D | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101316106, COSV101316554; called by muse, mutect2, varscan2
- AFAP1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as rs749129062, COSV61794643; called by muse, mutect2, varscan2
- ANK3 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs867695079, COSV99782494; called by muse, mutect2
- AOC2 | c.587A>C p.N196T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as COSV99513811; called by muse, mutect2, varscan2
- APOB | c.7075G>C p.D2359H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99268227; called by muse, mutect2, varscan2
- APOF | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772261296, COSV58474162; called by muse, mutect2, varscan2
- ARHGAP17 | c.1006A>T p.M336L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.941); catalogued as COSV99254090; called by muse, mutect2, varscan2
- ARHGAP31 | c.807G>T p.R269S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1201385098, COSV99957771; called by muse, mutect2, varscan2
- ARID5B | c.1639C>G p.L547V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99688841, COSV99690492; called by muse, mutect2, varscan2
- ASXL3 | c.5286A>T p.K1762N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99326738; called by muse, mutect2, varscan2
- ATP5PF | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535585; called by muse, mutect2, varscan2
- AXL | c.2091C>G p.I697M (on ENST00000301178 / NM_021913.5; = p.I688M on NM_001699.6) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99997298; called by muse, mutect2, varscan2
- BAZ1A | c.2722C>G p.L908V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701219; called by muse, mutect2, varscan2
- BAZ1B | c.3124C>G p.L1042V | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100290165; called by muse, mutect2
- CAMK2A | c.1100A>T p.E367V (on ENST00000348628 / NM_171825.2; = p.E378V on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100652056; called by muse, mutect2
- CCDC57 | c.1391A>T p.Q464L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100492685; called by muse, mutect2, varscan2
- CCDC87 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs762394264, COSV59579483, COSV59579788; called by muse, mutect2, varscan2
- CCR6 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100551212; called by muse, mutect2, varscan2
- CDH2 | c.2468G>T p.R823L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99298644; called by muse, mutect2, varscan2
- CDH26 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1426212768, COSV99723006; called by muse, mutect2, varscan2
- CDK14 | c.514G>A p.E172K (on ENST00000380050 / NM_001287135.2; = p.E154K on NM_012395.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99726967, COSV99727612; called by muse, mutect2, varscan2
- CDX4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100999122; called by muse, mutect2, varscan2
- CEMIP2 | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100987518; called by muse, mutect2, varscan2
- CEP95 | c.2307G>C p.K769N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101616344; called by muse, mutect2, varscan2
- CFAP46 | c.5677C>A p.H1893N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV99585618; called by muse, mutect2, varscan2
- CFAP65 | c.5254G>C p.E1752Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100445963; called by muse, mutect2, varscan2
- CLPB | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as COSV99578712; called by muse, mutect2
- CLPTM1L | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57991529; called by muse, mutect2, varscan2
- CNTN4 | c.72T>A p.H24Q | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101281604; called by muse, mutect2, varscan2
- COL22A1 | c.3770C>T p.P1257L | Missense Mutation (SNP) | VAF 73/431 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367820652; called by muse, mutect2, varscan2
- COL4A2 | c.3738G>C p.Q1246H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.885); catalogued as COSV100847492; called by muse, mutect2, varscan2
- COPA | c.2198A>T p.Y733F | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1390727057, COSV99616873; called by muse, mutect2, varscan2
- COQ2 | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270118; called by muse, mutect2, varscan2
- CPAMD8 | c.5095G>C p.A1699P (on ENST00000651564; = p.A1652P on NM_015692.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as COSV101488607; called by muse, mutect2, varscan2
- DDX18 | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs974470315, COSV99604827; called by muse, mutect2, varscan2
- DISP3 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV99610036; called by muse, mutect2, varscan2
- DNA2 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100622828; called by muse, mutect2, varscan2
- DNAH7 | c.10682C>G p.S3561C | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV100417697; called by muse, mutect2
- DNAH7 | c.7626A>G p.I2542M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); catalogued as COSV100417701; called by muse, mutect2, varscan2
- DNAH7 | c.5857C>G p.L1953V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100417675, COSV100417704; called by muse, mutect2, varscan2
- DNAJB11 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as rs1446240668, COSV54003517; called by muse, mutect2, varscan2
- DPYD | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV100929468; called by muse, mutect2, varscan2
- DUS1L | c.30G>C p.W10C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100152642; called by muse, mutect2, varscan2
- DYNC1I1 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100268810, COSV61468022; called by muse, mutect2, varscan2
- DYRK1A | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV58294828; called by muse, mutect2, varscan2
- EBAG9 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100520915; called by muse, mutect2, varscan2
- EGFLAM | c.2582G>C p.R861T (on ENST00000354891 / NM_001205301.2; = p.R853T on NM_152403.4) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59292810, COSV59303467; called by muse, mutect2, varscan2
- EPB41L3 | c.1369A>G p.K457E | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as rs767287627, COSV100550354; called by muse, mutect2, varscan2
- ERCC3 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 139/515 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53427098; called by muse, mutect2, varscan2
- ETV5 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777358489, COSV100112005, COSV60506461; called by muse, mutect2, varscan2
- EVI2B | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100445680; called by muse, mutect2, varscan2
- EXOC1 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV100638028; called by muse, mutect2, varscan2
- FAM135B | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99358265; called by muse, mutect2, varscan2
- FAM71C | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100175842, COSV60943493; called by muse, mutect2, varscan2
- FAT3 | c.2999A>G p.Y1000C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99971344; called by muse, mutect2, varscan2
- FBXL7 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100310953; called by muse, mutect2, varscan2
- FBXO48 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100377062; called by muse, mutect2, varscan2
- FGD6 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100676841; called by muse, mutect2, varscan2
- FLNC | c.353-1G>C p.X118_splice | Splice Site (SNP) | VAF 35/90 reads (39%) | catalogued as rs778074748, COSV100368791; called by muse, varscan2
- FLNC | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100368792; called by muse, varscan2
- FMNL3 | c.2418G>A p.M806I | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99527027; called by muse, mutect2, varscan2
- FOXN1 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99881541; called by muse, mutect2, varscan2
- FRAS1 | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV99355963; called by muse, mutect2, varscan2
- FRMPD2 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100564214; called by muse, mutect2, varscan2
- G6PD | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100855144; called by muse, mutect2, varscan2
- GDPD2 | c.1538+1G>C p.X513_splice | Splice Site (SNP) | VAF 22/39 reads (56%) | catalogued as COSV100978712; called by muse, varscan2
- GFRAL | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200268366, COSV100476006; called by muse, mutect2, varscan2
- GOLGA7B | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100086160; called by muse, mutect2, varscan2
- GPR37 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV58258464, COSV58259159; called by muse, mutect2, varscan2
- GRIN2A | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100411129; called by muse, mutect2, varscan2
- GRM1 | c.2882A>C p.E961A | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV51386336; called by muse, mutect2
- GRN | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99275136, COSV99275204; called by muse, mutect2, varscan2
- HEATR1 | c.2503A>T p.M835L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230488285, COSV100857802; called by muse, mutect2, varscan2
- HEG1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs370267359; called by muse, mutect2, varscan2
- HMCN1 | c.13114G>T p.E4372* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV54885081, COSV99636188; called by muse, mutect2, varscan2
- ICE2 | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as COSV99831859; called by muse, mutect2, varscan2
- IGHV1-45 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1435551712; called by muse, mutect2, varscan2
- IGSF10 | c.6240C>G p.I2080M | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99195661; called by muse, varscan2
- IGSF10 | c.6188C>T p.S2063F | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99195704; called by muse, varscan2
- IGSF10 | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56781922, COSV99195736; called by muse, mutect2, varscan2
- IL9R | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99730251; called by muse, mutect2, varscan2
- INSC | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101089711; called by muse, mutect2, varscan2
- INSRR | c.2920G>A p.V974M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100948126; called by muse, mutect2, varscan2
- JAK2 | c.1121G>C p.R374T | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101073643, COSV101079741, COSV67613417; called by muse, mutect2, varscan2
- JAK2 | c.3057C>G p.F1019L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101079743; called by muse, mutect2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KIAA0100 | c.5848G>C p.E1950Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99972330; called by muse, mutect2, varscan2
- KIAA0100 | c.3689G>T p.R1230L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV66492748, COSV66495477; called by muse, mutect2, varscan2
- KIAA1549 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 31/147 reads (21%) | catalogued as COSV54324134; called by muse, mutect2, varscan2
- KIAA2013 | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.113); catalogued as COSV100927155; called by muse, mutect2, varscan2
- KIF12 | c.859G>C p.E287Q (on ENST00000640217; = p.E149Q on NM_138424.1) | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100936297; called by muse, mutect2, varscan2
- KIF1A | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242397, COSV57503638; called by muse, mutect2
- KIF24 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527449185, COSV100799367; called by muse, mutect2, varscan2
- KLRC2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 66/264 reads (25%) | catalogued as COSV101122757; called by muse, mutect2, varscan2
- LHX6 | c.802C>T p.Q268* (on ENST00000373755 / NM_001242334.2; = p.Q297* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100493618; called by muse, mutect2, varscan2
- LIN28B | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.98); catalogued as COSV100559119; called by muse, mutect2, varscan2
- LRATD2 | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as COSV100513670; called by muse, mutect2, varscan2
- LRP1B | c.9803G>A p.R3268K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV101261422, COSV67200997; called by muse, mutect2
- LRP2 | c.3478C>G p.R1160G | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55543401, COSV99790352; called by muse, mutect2, varscan2
- MBOAT1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100209235; called by muse, mutect2, varscan2
- MEST | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1563024050, COSV99784343; called by muse, mutect2, varscan2
- MGAM | c.4623G>A p.M1541I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV101527772, COSV99071103; called by muse, mutect2
- MORC2 | c.1267C>T p.P423S (on ENST00000397641 / NM_001303256.3; = p.P361S on NM_014941.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99310465; called by muse, mutect2, varscan2
- MPHOSPH8 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV64055811; called by muse, mutect2, varscan2
- MPND | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99515392; called by muse, mutect2, varscan2
- MRC2 | c.1783T>C p.W595R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316796; called by muse, mutect2, varscan2
- MS4A14 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV100280753; called by muse, mutect2
- MTMR2 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV100656855; called by muse, mutect2, varscan2
- MYCBP2 | c.1643C>T p.S548L (on ENST00000357337; = p.S586L on NM_015057.5) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs982487000, COSV100631988, COSV62039062; called by muse, mutect2, varscan2
- MYH1 | c.193del p.E65Kfs*6 | Frame Shift Del (DEL) | VAF 88/206 reads (43%) | catalogued as COSV55439016, COSV55443205; called by mutect2, pindel, varscan2
- MYLK2 | c.1398G>A p.W466* | Nonsense Mutation (SNP) | VAF 45/168 reads (27%) | catalogued as rs866504595, COSV101044950; called by muse, mutect2, varscan2
- N4BP2L2 | c.115A>C p.S39R | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99912731; called by muse, mutect2, varscan2
- NABP1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100323113; called by muse, mutect2, varscan2
- NCK2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99257062; called by muse, mutect2, varscan2
- NKAIN1 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99744781; called by muse, mutect2, varscan2
- NLGN4X | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324065; called by muse, mutect2, varscan2
- NLRP3 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100276690; called by muse, mutect2, varscan2
- NOVA1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948475; called by muse, mutect2
- NOXRED1 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as rs1231702287, COSV100033242; called by muse, mutect2, varscan2
- NRDC | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV100544106; called by muse, mutect2, varscan2
- OR2J3 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV101013667, COSV65848677, COSV99058513; called by muse, mutect2, varscan2
- OR4A16 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV100125043, COSV59044247; called by muse, mutect2, varscan2
- OR4C6 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as rs558855783, COSV100051865, COSV99041468; called by muse, mutect2, varscan2
- OR4F15 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 11/162 reads (7%) | catalogued as COSV100173960; called by muse, mutect2
- OR6N2 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59412959; called by muse, mutect2, varscan2
- OR6T1 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100190193; called by muse, mutect2, varscan2
- OR8D2 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100659122, COSV62488395; called by muse, mutect2, varscan2
- OTOF | c.2810A>T p.K937M (on ENST00000272371 / NM_194248.3; = p.K190M on NM_004802.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.817); catalogued as COSV99719053; called by muse, mutect2, varscan2
- OTX1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV99246547; called by muse, mutect2, varscan2
- PAN3 | c.1691-1G>A p.X564_splice | Splice Site (SNP) | VAF 22/106 reads (21%) | catalogued as COSV99145175; called by muse, mutect2, varscan2
- PCDH11X | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV53502706; called by muse, mutect2
- PCDHA11 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 175/311 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.409); catalogued as COSV56480379; called by muse, mutect2, varscan2
- PCDHA5 | c.1605C>G p.S535R | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); catalogued as rs782708601, COSV100972560; called by muse, mutect2, varscan2
- PCDHB11 | c.1284A>G p.I428M | Missense Mutation (SNP) | VAF 89/149 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV100697189; called by muse, mutect2, varscan2
- PCDHGA12 | c.375C>G p.D125E | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99342453; called by muse, mutect2, varscan2
- PDE9A | c.1360A>T p.K454* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99372253; called by muse, mutect2, varscan2
- PDSS1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs770801485, COSV100873630; called by muse, mutect2, varscan2
- PEAK1 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100433468; called by muse, mutect2, varscan2
- PGK2 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1422451650, COSV59162906, COSV59163938; called by muse, mutect2
- PHACTR3 | c.1545G>C p.R515S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733263, COSV63030899; called by muse, mutect2, varscan2
- PHF1 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100992691; called by muse, mutect2
- PHF3 | c.3884G>A p.R1295K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100013048; called by muse, mutect2, varscan2
- PITX2 | c.583C>T p.P195S (on ENST00000354925 / NM_001204397.1; = p.P202S on NM_000325.6) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1475929130, COSV100146504, COSV60742421; called by muse, mutect2, varscan2
- PKN3 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV52579830, COSV99403943; called by muse, mutect2, varscan2
- PLG | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99804805, COSV99805148; called by muse, mutect2, varscan2
- POGZ | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as rs749315555, COSV99305300; called by muse, mutect2, varscan2
- POSTN | c.1986A>T p.K662N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV101123503, COSV65713396; called by muse, mutect2
- POU1F1 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV100622783; called by muse, mutect2, varscan2
- PPM1E | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100376683; called by muse, mutect2, varscan2
- PRB2 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 100/633 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV66982811; called by muse, varscan2
- PROSER3 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs557132741, COSV99994793; called by muse, mutect2, varscan2
- QSOX1 | c.1926G>C p.L642F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV62581397; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99240944; called by muse, mutect2, varscan2
- RAD52 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99942727; called by muse, mutect2, varscan2
- RAD54B | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100280243; called by muse, mutect2, varscan2
- RALGAPB | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 50/207 reads (24%) | catalogued as COSV99485857; called by muse, mutect2, varscan2
- RBPJL | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.029); catalogued as rs773242322, COSV100637175; called by muse, mutect2, varscan2
- RETREG2 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99811729; called by muse, mutect2, varscan2
- RICTOR | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57123279; called by muse, mutect2, varscan2
- RNF186 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs142010502; called by muse, mutect2, varscan2
- RNF6 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100644677; called by muse, mutect2, varscan2
- ROMO1 | c.186G>C p.Q62H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV99037129; called by muse, mutect2, varscan2
- RSPH10B2 | c.626T>A p.V209E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV99786402; called by muse, mutect2, varscan2
- SACS | c.9059C>T p.S3020F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV101207747, COSV104428844; called by muse, mutect2
- SCN3A | c.3625G>C p.E1209Q | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99032294; called by muse, mutect2, varscan2
- SCN9A | c.5914G>C p.D1972H (on ENST00000303354; = p.D1961H on NM_002977.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100314310; called by muse, mutect2, varscan2
- SDS | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99785522; called by muse, mutect2, varscan2
- SEMA5B | c.2281-1G>T p.X761_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99533272; called by muse, mutect2, varscan2
- SFTPA2 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64882142, COSV64882163; called by muse, mutect2, varscan2
- SFTPA2 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.383); catalogued as COSV100958808; called by muse, mutect2
- SGIP1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.855); catalogued as COSV52765855, COSV99393006; called by muse, mutect2, varscan2
- SHB | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100891911; called by muse, mutect2, varscan2
- SHPRH | c.1860C>G p.I620M | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV99262723; called by muse, mutect2, varscan2
- SI | c.3448C>T p.H1150Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100017276; called by muse, mutect2, varscan2
- SI | c.709T>A p.Y237N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV100017278; called by muse, mutect2, varscan2
- SLC12A8 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100103167; called by muse, mutect2, varscan2
- SLC30A7 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100725608; called by muse, mutect2, varscan2
- SLC35E3 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100098106; called by muse, mutect2, varscan2
- SLC5A7 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV50894443, COSV99887281; called by muse, mutect2, varscan2
- SLCO1B1 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV57007047, COSV99919199; called by muse, mutect2, varscan2
- SNRNP200 | c.3184C>G p.L1062V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100108073; called by muse, mutect2, varscan2
- SNX16 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100629709, COSV62036237; called by muse, mutect2, varscan2
- SON | c.2198C>G p.S733C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99279949; called by muse, mutect2, varscan2
- SON | c.5365G>T p.D1789Y | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1203563501, COSV99279953; called by muse, mutect2, varscan2
- SOX11 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100431474; called by muse, varscan2
- SPATA6L | c.427C>T p.L143F (on ENST00000461761 / NM_001353484.2; = p.L85F on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99795142; called by muse, mutect2, varscan2
- ST18 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV99391129; called by muse, mutect2, varscan2
- STAB2 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV101186348, COSV66341598; called by muse, mutect2
- STK39 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV100597326; called by muse, mutect2, varscan2
- STT3A | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV101205293; called by muse, mutect2, varscan2
- SYCP1 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs532386607, COSV101051210; called by muse, mutect2, varscan2
- SYNGR4 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs746053316, COSV100785151; called by muse, mutect2
- SYNJ1 | c.609G>T p.L203F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100449664; called by muse, mutect2
- TCHP | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100452651; called by muse, mutect2
- TENM1 | c.5808C>G p.I1936M | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV100951031, COSV64424208; called by muse, mutect2, varscan2
- THSD7B | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.967); catalogued as COSV55713683, COSV99758423; called by muse, mutect2, varscan2
- TLE1 | c.235-1G>C p.X79_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100916027; called by muse, mutect2, varscan2
- TMCC1 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100261331; called by muse, mutect2, varscan2
- TMEM67 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1226328805, COSV100019932; called by muse, mutect2, varscan2
- TNK2 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1325257065, COSV100361735; called by muse, mutect2, varscan2
- TNR | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99691740; called by muse, mutect2, varscan2
- TOR1AIP1 | c.619A>G p.S207G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs759786680, COSV99621678; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV99621680; called by muse, mutect2, varscan2
- TPMT | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015521; called by muse, mutect2, varscan2
- TRMT2A | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005499939, COSV99350328; called by muse, mutect2, varscan2
- TRPC6 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs908640812, COSV60260764; called by muse, mutect2
- TRPS1 | c.2904G>C p.R968S (on ENST00000220888 / NM_001330599.2; = p.R981S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99634663; called by muse, mutect2, varscan2
- TTLL3 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs377604036; called by muse, mutect2, varscan2
- TTN | c.59258G>C p.G19753A (on ENST00000591111; = p.G12329A on NM_003319.4) | Missense Mutation (SNP) | VAF 36/137 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV100631125; called by muse, mutect2, varscan2
- TTN | c.52072G>A p.D17358N (on ENST00000591111; = p.D9934N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV60276734; called by muse, mutect2, varscan2
- TTN | c.18348G>C p.M6116I (on ENST00000591111; = p.M5189I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | PolyPhen benign (0.078); catalogued as COSV59950755, COSV60104563; called by muse, mutect2, varscan2
- TUBE1 | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100037211; called by muse, mutect2, varscan2
- UBQLN4 | c.763C>G p.P255A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100849353; called by muse, mutect2
- UBR4 | c.14707G>C p.E4903Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1214132144, COSV100921949; called by muse, mutect2
- UNC93B1 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99916440; called by muse, mutect2
- USP48 | c.217C>G p.H73D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100380270; called by muse, mutect2, varscan2
- UTRN | c.2551C>T p.L851F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV100840670; called by muse, mutect2, varscan2
- VPS13B | c.5038C>G p.Q1680E | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV100663767; called by muse, mutect2
- WT1 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as COSV100189036, COSV60081141; called by muse, mutect2, varscan2
- WWC1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99515992; called by muse, mutect2
- ZCCHC12 | c.730A>T p.S244C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100038684; called by muse, mutect2, varscan2
- ZCCHC14 | c.2377T>G p.C793G (on ENST00000268616; = p.C930G on NM_015144.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV99234589; called by muse, mutect2, varscan2
- ZFYVE26 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100720703; called by muse, mutect2, varscan2
- ZNF184 | c.1292C>G p.S431* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV53003066; called by muse, mutect2, varscan2
- ZNF287 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV101209441; called by muse, mutect2, varscan2
- ZNF34 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100603402; called by muse, mutect2, varscan2
- ZNF420 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100421531; called by muse, mutect2, varscan2
- ZNF436 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100011357; called by muse, mutect2, varscan2
- ZNF470 | c.1509T>A p.H503Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100401415, COSV57970845; called by muse, mutect2, varscan2
- ZNF600 | c.1409A>T p.Y470F | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100593116; called by muse, mutect2, varscan2
- ZNF714 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV99395629; called by muse, mutect2, varscan2
- ZNF83 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV56530304; called by muse, mutect2, varscan2
- ZNHIT2 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99659424; called by muse, mutect2, varscan2
- ACACB | c.5462del p.G1821Afs*44 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- HIPK1 | c.3565del p.R1189Efs*11 (on ENST00000369558 / NM_001369806.1; = p.R795Efs*11 on NM_181358.2) | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | called by mutect2, pindel, varscan2
- RBM10 | c.1796_1798del p.N599_A600delinsT | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- SRCAP | c.2147_2169del p.N716Ifs*24 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel
- TAF15 | c.1151C>T p.P384L (on ENST00000605844 / NM_139215.3; = p.P381L on NM_003487.4) | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TONSL | c.1326_1333del p.R443Afs*6 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- TRAV18 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZBTB41 | c.1891C>G p.H631D | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZDHHC18 | c.727_728del p.S243Pfs*67 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by pindel, varscan2
- ZNF26 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF680 | c.583_590del p.S195Nfs*9 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- ZSCAN26 | c.847C>T p.Q283* (on ENST00000623276 / NM_001111039.2; = p.Q149* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- A1BG | c.114G>A p.L38= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV99568703; called by muse, mutect2, varscan2
- ACSM2B | c.1312C>A p.R438= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as COSV100313173; called by muse, mutect2, varscan2
- ADAM30 | c.1401A>C p.A467= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV101023991; called by muse, mutect2, varscan2
- ADGRB3 | c.261T>G p.A87= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV101002009; called by muse, mutect2, varscan2
- ADGRG7 | c.954C>A p.T318= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs752030472, COSV99841577; called by muse, mutect2, varscan2
- ALAS1 | c.288C>T p.P96= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100050491; called by muse, mutect2, varscan2
- ANKRD30A | c.3261G>A p.L1087= (on ENST00000611781; = p.L1031= on NM_052997.2) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV64614425; called by muse, mutect2
- APOB | c.1110G>A p.L370= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV51942655; called by muse, mutect2
- ARMC4 | c.2586C>G p.L862= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1172411870, COSV59456735, COSV59462668; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.525G>A p.G175= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as COSV100771994; called by muse, mutect2, varscan2
- ASMTL | c.1161C>G p.L387= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as COSV101187956; called by muse, mutect2, varscan2
- ATM | c.105A>G p.R35= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV53724314; called by muse, mutect2, varscan2
- AXDND1 | c.1890A>G p.E630= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100858690; called by muse, mutect2
- BARD1 | c.1422G>A p.L474= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99639944; called by muse, mutect2, varscan2
- CDH10 | c.2211C>G p.A737= | Silent (SNP) | VAF 63/222 reads (28%) | catalogued as COSV100053203; called by muse, mutect2, varscan2
- CLEC17A | c.48C>A p.T16= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100355154, COSV100355579; called by muse, mutect2, varscan2
- CYP26C1 | c.627G>A p.T209= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1408746301, COSV99592537; called by muse, mutect2
- DENND4C | c.5322C>G p.L1774= (on ENST00000434457 / NM_001330640.2; = p.L1725= on NM_017925.7) | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as COSV100727607, COSV63009756; called by muse, mutect2, varscan2
- DRD3 | c.1185C>G p.L395= | Silent (SNP) | VAF 130/508 reads (26%) | catalogued as COSV99879711; called by muse, mutect2, varscan2
- DVL3 | c.1389G>A p.E463= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV100493814; called by muse, mutect2, varscan2
- EHBP1L1 | c.1725G>A p.E575= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100500039; called by muse, mutect2, varscan2
- FAM171B | c.2169G>A p.E723= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100489038; called by muse, mutect2, varscan2
- FLRT2 | c.1326C>T p.L442= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV58147383; called by muse, mutect2, varscan2
- FLT1 | c.3460C>T p.L1154= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56728377, COSV99167370; called by muse, mutect2, varscan2
- GHDC | c.351G>A p.P117= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as rs371516105; called by muse, mutect2, varscan2
- GPR26 | c.921G>A p.E307= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1482159603, COSV99501129; called by muse, mutect2, varscan2
- GPRC6A | c.27C>T p.T9= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1299809793, COSV59952954; called by muse, mutect2, varscan2
- GRM1 | c.3216G>T p.P1072= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs376765247, COSV99269160; called by muse, mutect2
- GTF3C1 | c.447G>C p.L149= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100649732; called by muse, mutect2, varscan2
- HERC2 | c.14169C>G p.V4723= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99876878; called by muse, mutect2, varscan2
- IL22RA1 | c.165C>T p.I55= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs779925405, COSV99583297; called by muse, mutect2, varscan2
- IL7R | c.1074A>G p.P358= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs996923512, COSV100286696; called by muse, mutect2, varscan2
- INTS1 | c.582C>T p.I194= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV101248356; called by muse, mutect2, varscan2
- ITGA11 | c.273C>A p.V91= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100242236; called by muse, mutect2, varscan2
- JAML | c.528C>T p.R176= (on ENST00000356289 / NM_001098526.2; = p.R166= on NM_153206.3) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs762252806, COSV99409757; called by muse, mutect2, varscan2
- KCNC1 | c.213C>T p.Y71= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99789765; called by muse, mutect2, varscan2
- LRG1 | c.543C>T p.P181= | Silent (SNP) | VAF 70/268 reads (26%) | catalogued as rs545216965, COSV100015152; called by muse, mutect2, varscan2
- LSAMP | c.111C>G p.G37= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1559870834, COSV100372902, COSV61297846; called by muse, mutect2, varscan2
- LYZL6 | c.66C>T p.I22= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- MAOB | c.1479C>T p.L493= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV100956254, COSV65206484; called by muse, mutect2, varscan2
- METTL24 | c.540C>T p.C180= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100133665; called by muse, mutect2, varscan2
- MSH4 | c.1875A>G p.S625= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV99592583; called by muse, mutect2, varscan2
- MYH13 | c.318C>G p.L106= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as COSV52829509, COSV99355534; called by muse, mutect2, varscan2
- NOMO1 | c.1437G>A p.L479= | Silent (SNP) | VAF 66/230 reads (29%) | catalogued as COSV99814499; called by muse, mutect2, varscan2
- NSL1 | c.714G>A p.Q238= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as COSV100875675; called by muse, mutect2, varscan2
- NSMAF | c.2313A>G p.L771= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as COSV99233494; called by muse, mutect2, varscan2
- OR6S1 | c.975C>T p.L325= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as COSV100289537, COSV100289583; called by muse, mutect2, varscan2
- OR7G1 | c.351C>G p.V117= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV53319303, COSV99528811; called by muse, mutect2, varscan2
- OR8K5 | c.624C>T p.I208= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100537337; called by muse, mutect2, varscan2
- OSBPL7 | c.540G>A p.P180= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs755698514, COSV99137070; called by muse, mutect2, varscan2
- PAPOLG | c.1530T>C p.S510= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99475130; called by muse, mutect2, varscan2
- PCDHB5 | c.2115C>G p.L705= | Silent (SNP) | VAF 120/212 reads (57%) | catalogued as COSV99169616; called by muse, mutect2, varscan2
- PCLO | c.14928G>A p.P4976= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773423824, COSV100429207, COSV61624491; called by muse, mutect2, varscan2
- PFN2 | c.177C>T p.F59= | Silent (SNP) | VAF 118/276 reads (43%) | catalogued as COSV99526216; called by muse, mutect2, varscan2
- PI4KB | c.2130G>A p.L710= (on ENST00000368873 / NM_001369623.1; = p.L722= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99650199; called by muse, mutect2, varscan2
- PLEKHG5 | c.612G>C p.L204= (on ENST00000400915 / NM_001042663.3; = p.L167= on NM_020631.6) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100557176; called by muse, mutect2, varscan2
- PLXNA1 | c.4860C>T p.L1620= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs769218566, COSV99304156; called by muse, mutect2, varscan2
- PMS1 | c.1770C>G p.L590= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100575797, COSV59720719; called by muse, mutect2, varscan2
- PTCD1 | c.165C>T p.L55= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs150026614; called by muse, mutect2, varscan2
- PTDSS1 | c.357C>G p.L119= | Silent (SNP) | VAF 66/458 reads (14%) | catalogued as COSV100428416, COSV100428964, COSV61266264; called by muse, mutect2, varscan2
- RASGEF1C | c.204G>A p.L68= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV100746418; called by muse, mutect2, varscan2
- RAVER2 | c.1542G>C p.T514= (on ENST00000294428 / NM_001366165.1; = p.T501= on NM_018211.4) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99605693; called by mutect2, varscan2
- REXO4 | c.63T>A p.G21= | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as COSV100747230; called by muse, mutect2, varscan2
- RIF1 | c.5877G>A p.L1959= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs995461230, COSV99691287; called by muse, mutect2, varscan2
- RPTN | c.213T>C p.F71= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV100285813; called by muse, mutect2, varscan2
- RTEL1 | c.2085C>T p.I695= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs774642602, COSV58900955; called by muse, mutect2, varscan2
- RTN3 | c.3069C>T p.L1023= (on ENST00000377819 / NM_001265589.2; = p.L227= on NM_006054.4) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100380376; called by muse, mutect2, varscan2
- RTN4 | c.1710G>A p.K570= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV100464018, COSV58271405; called by muse, mutect2, varscan2
- SH3BP2 | c.486C>T p.I162= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100697051; called by muse, mutect2, varscan2
- SPOUT1 | c.321C>T p.F107= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs757692599, COSV100778269; called by muse, mutect2, varscan2
- TAF1L | c.3159A>G p.T1053= | Silent (SNP) | VAF 109/188 reads (58%) | catalogued as COSV99645440; called by muse, mutect2, varscan2
- TCF21 | c.438C>T p.H146= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99399771; called by muse, mutect2, varscan2
- TLR4 | c.831A>T p.L277= (on ENST00000355622 / NM_138554.5; = p.L237= on NM_003266.4) | Silent (SNP) | VAF 69/142 reads (49%) | catalogued as COSV100790696; called by muse, mutect2, varscan2
- TNN | c.996T>A p.R332= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99513106; called by muse, mutect2, varscan2
- YIPF4 | c.534C>G p.L178= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV53212987; called by muse, mutect2, varscan2
- YRDC | c.594C>T p.L198= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100888714; called by muse, mutect2, varscan2
- ZFHX4 | c.7185C>A p.P2395= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as COSV99268041; called by muse, mutect2
- ZIC1 | c.933G>A p.K311= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs748631648, COSV99292469; called by muse, mutect2, varscan2
- ZNFX1 | c.1932A>G p.Q644= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV100871020; called by muse, mutect2, varscan2
- DNAH14 | c.749-4188A>G | Intron (SNP) | VAF 23/68 reads (34%) | catalogued as rs202149727, COSV100835981; called by muse, mutect2, varscan2
- PRRX1 | c.599+3931C>A | Intron (SNP) | VAF 37/164 reads (23%) | catalogued as rs146552721, COSV53419181; called by muse, mutect2, varscan2
- S100A13 | c.*2G>C | 3'UTR (SNP) | VAF 49/188 reads (26%) | catalogued as COSV100275378; called by muse, mutect2, varscan2
- SNORD115-36 | n.75T>A | RNA (SNP) | VAF 66/174 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10303+2607T>C | Intron (SNP) | VAF 26/88 reads (30%) | catalogued as rs931429979, COSV59935614; called by muse, mutect2, varscan2
